Surgical pathology report (de-identified scan), TCGA case TCGA-31-1950, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1950-01A (Primary Tumor).

[page 1 of 2]
Specimen Type:

1: OVARIES

2: Omentum

Clinical Details:

No details given

TCGA-31-1950

Macroscopic Description:

1) Ovaries:

Two ovaries received, the larger ovary on external examination appears partly solid and partly cystic and measures 12 x 13 x 11cm and weighs more than 1500gms. On external examination there are irregular nodular and solid areas on the ovarian surface, these appear to be areas of capsular breach. The external surface is inked black. An attached fallopian tube is identified and measures 8cm in length and 0.5cm in diameter. On slicing the larger ovary it is partly solid and partly cystic, there are abundant papillary excrescences and formations on the inner ovarian cyst lining and the solid areas are white and firm. The smaller partly cystic ovary measures 7.7 x 5.5 x 3cm and the attached fallopian tube measures 4cm in length and 0.7cm in diameter. On the external surface of the smaller ovary there are large, solid/papillary areas and areas of irregularity. On slicing the ovary the inner surface shows papillary excrescences and is irregular. The smaller ovary weighs 205.8gms.

BLOCKS: 1A: Larger ovary, area of capsular breach: 1,1pc.
1B: Larger ovary with irregular external surface: 1,2pcs.
1C-F: Larger ovary, cyst wall with solid internal projections: 1pc in each.
1G-H: Larger ovary, cyst wall with internal solid areas: 1pc in each.
1K: Larger ovary: solid area larger cyst: 1,1pc.
1L: RS larger cyst wall: 1,2pcs.
1M: RS solid area: 1,1pc.
1N: TS fallopian tube larger cyst: 1,2pcs.
1P-Q: Smaller ovary, irregular/solid papillary areas: 1pc in each.

[page 2 of 2]
1R: TS fallopian tube smaller ovary, including 0.4cm cyst ? paratubal: 1,2pcs.
1S: Smaller ovary, solid area: 1,1pc.
1T: Smaller ovary, cyst wall: 1,3pcs.
1U: Smaller ovary, cyst wall: 1,2pcs.
1V: Smaller ovary, solid area: 1,1pc.

TCGA-31-1950

2) Omentum:

A piece of omentum measuring 23 x 5 x 1cm. On slicing the omentum white nodules are identified (query representing tumour), the largest measuring 2 x 0.7 x 1.5cm. There are in addition multiple smaller nodules.

BLOCKS: 2A: RS largest omental nodule: 1,2pcs.
2B-C: RS other omental nodules: 2pcs in each.
2D: RS separate omental nodules: 1,1pc.
2E-F: Background omentum: 1pc in each.

Microscopic Description:

1) Ovaries:

Both ovaries show a dense infiltration of moderately atypical glandular cells forming complex papillary and cystic structures. There is stratification of the cells lining these structures. The cells are pleomorphic, hyperchromatic and show numerous mitotic figures. There is invasion into the underlying stroma, with areas of necrosis and haemorrhage. Psammoma bodies are seen. The tumour extends through the inked capsular surface margins. Both fallopian tubes show no evidence of tumour invasion. The appearances are those of a moderately differentiated serous papillary cystadenocarcinoma.

2) Omentum:

The omentum shows infiltration of the omental fat by atypical glandular cells forming papillary structures, both in the nodular areas, as well as in the background omentum. The appearances are similar to the cells in the ovarian specimens. The tumour in the largest nodule measures up to 19.7 mm.

The peritoneal fluid contains malignant cells

Final Diagnosis:

1-2) OVARIES, TUBES AND OMENTUM:

- **GRADE 2 SEROUS PAPILLARY CYSTADENOCARCINOMA OF THE OVARIES, IN BOTH OVARIES, EXTENDING THROUGH THE CAPSULAR SURFACE, WITH METASTASIS IN THE OMENTUM.**
- **T3b Nx Mx (FIGO STAGE IIIC)**

Source: NCI Genomic Data Commons file 4ef294a7-149a-4e89-8019-f4db6d61da92 (TCGA-31-1950.4ED80CBD-E56D-4D09-B8AC-2B6535346B73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).